Somatic mutation profile of tumor specimen MP2PRT-PAPUTT-TMP1-A (aliquot MP2PRT-PAPUTT-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPUTT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,212 days).
Specimen MP2PRT-PAPUTT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a090cecc-d0a7-468a-b745-6f1fec4cd72c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUTT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUTT-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/163fe4e4-438a-45a9-8d78-34f6db34ac11

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4253G>A p.R1418H | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446306735, CM043738, CM144517, COSV100217047; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HCN1 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV100302374; called by muse, mutect2, varscan2
- PARP1 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1558233883; called by muse, mutect2
- PBX2 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as COSV66708762, COSV66708854; called by muse, mutect2
- PXDNL | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs769579619, COSV100684910, COSV62477078, COSV62496975; called by muse, mutect2
- RGS11 | c.1069C>G p.Q357E (on ENST00000397770 / NM_183337.3; = p.Q336E on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/413 reads (3%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.525); catalogued as rs1191824318; called by muse, mutect2
- ADGRV1 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ASNSD1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CD33 | c.974G>C p.C325S | Missense Mutation (SNP) | VAF 157/415 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-7 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2
- IGKV1OR2-108 | c.351del p.P118Pfs*? | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | called by pindel, varscan2
- NPRL2 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR11G2 | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- SOX3 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- CARD16 | c.258G>A p.T86= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- CSRNP3 | c.1257C>T p.H419= | Silent (SNP) | VAF 32/462 reads (7%) | catalogued as rs762453522; called by muse, mutect2
- IGF2R | c.5700C>T p.G1900= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as rs752770946, COSV63627379; called by muse, mutect2, varscan2
